Somatic mutation profile of tumor specimen 0DSL08 from CCDI case PBCHUF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 12.9 years (4,719 days).
Specimen 0DSL08: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a90b5029-9fec-487e-b9ce-b9f50d32a80b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSKZG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c196cf59-ca21-47a8-9ee2-f1b804393239

The open-access MAF lists 101 somatic variants for this specimen: 68 protein-altering or splice-affecting, 22 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 22, Nonsense Mutation 6, Intron 5, 3'UTR 3, Frame Shift Del 2, Splice Site 2, 5'UTR 2, In Frame Del 2, RNA 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 22/226 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2
- NF1 | c.5856G>A p.W1952* (on ENST00000358273 / NM_001042492.3; = p.W1931* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 20/200 reads (10%) | catalogued as rs1555534393, CM071891, CM076347, COSV62204834; ClinVar: pathogenic; called by muse, mutect2
- ACAP3 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 75/124 reads (60%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.835); catalogued as rs745335912; called by muse, mutect2, varscan2
- ATP9A | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.344); catalogued as COSV58767424; called by muse, mutect2, varscan2
- CPOX | c.658A>G p.K220E | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as rs756992469; called by muse, mutect2
- DDIAS | c.1780A>G p.T594A | Missense Mutation (SNP) | VAF 28/303 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs757519018; called by muse, mutect2
- GIT2 | c.2102G>C p.R701P (on ENST00000355312 / NM_057169.5; = p.R623P on NM_014776.5) | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV58079427; called by muse, mutect2, varscan2
- GNAT3 | c.668T>G p.F223C | Missense Mutation (SNP) | VAF 57/428 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68067728; called by muse, mutect2, varscan2
- GPR135 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV67749812; called by muse, mutect2, varscan2
- H1-8 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0.024); catalogued as rs147642525; called by muse, mutect2, varscan2
- HERC2 | c.2795A>G p.D932G | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.175); catalogued as COSV55318305; called by muse, mutect2
- IGF2R | c.4630G>A p.E1544K | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.762); catalogued as rs750522726; called by muse, varscan2
- ITPR2 | c.1480C>A p.L494M | Missense Mutation (SNP) | VAF 68/420 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67269204; called by muse, mutect2, varscan2
- KIAA0825 | c.1787C>T p.T596M | Missense Mutation (SNP) | VAF 29/365 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs776935393; called by muse, mutect2
- KLK3 | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs762600618; called by mutect2, varscan2
- LAMB1 | c.454C>G p.R152G | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55963202, COSV55969793; called by muse, mutect2
- MYPN | c.295C>G p.R99G | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV62731461; called by muse, mutect2, varscan2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 18/80 reads (23%) | catalogued as rs780417788; called by mutect2, varscan2
- PADI6 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs777483800; called by muse, mutect2, varscan2
- PLCH1 | c.2945C>T p.S982L (on ENST00000340059 / NM_001130960.2; = p.S974L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.369); catalogued as rs1560051139, COSV58187582; called by muse, mutect2, varscan2
- PXDNL | c.2658G>T p.Q886H | Missense Mutation (SNP) | VAF 46/472 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100681007; called by muse, mutect2, varscan2
- RANBP17 | c.2144G>C p.R715P | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as rs371474320; called by muse, mutect2, varscan2
- SCN3A | c.2398A>G p.T800A | Missense Mutation (SNP) | VAF 70/373 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs769244270, COSV51802755; called by muse, mutect2, varscan2
- SHANK2 | c.3664G>C p.A1222P | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53600959, COSV99573203; called by muse, mutect2, varscan2
- TAS1R1 | c.79del p.E27Sfs*27 | Frame Shift Del (DEL) | VAF 50/151 reads (33%) | catalogued as COSV100062657, COSV60228378; called by mutect2, varscan2
- TUBA3D | c.638G>T p.C213F | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); catalogued as COSV58313200; called by mutect2, varscan2
- A2ML1 | c.3068A>G p.Y1023C | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP6 | c.284C>A p.S95* | Nonsense Mutation (SNP) | VAF 37/155 reads (24%) | called by muse, mutect2, varscan2
- AMELY | c.338A>G p.Q113R (on ENST00000383036 / NM_001364814.1; = p.Q99R on NM_001143.1) | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AQP12B | c.405G>A p.M135I (on ENST00000621682; = p.M147I on NM_001102467.2) | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.038); called by muse, mutect2
- ASB2 | c.490+2T>G p.X164_splice | Splice Site (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2
- ATG101 | c.267C>G p.N89K | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCOR | c.4352_4358del p.P1451Hfs*31 (on ENST00000378444 / NM_001123385.2; = p.P1417Hfs*31 on NM_017745.6) | Frame Shift Del (DEL) | VAF 36/54 reads (67%) | called by mutect2, varscan2
- CBFA2T3 | c.635_637del p.T212del | In Frame Del (DEL) | VAF 28/92 reads (30%) | called by mutect2, varscan2
- CCDC8 | c.1538G>C p.G513A | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- CDC14C | c.481A>T p.N161Y (on ENST00000428251; = p.N54Y on NM_152627.3) | Missense Mutation (SNP) | VAF 47/322 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CDK5R2 | c.548C>G p.T183S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- CENPF | c.2071G>C p.V691L | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CSNK1G3 | c.1150C>T p.L384F | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- DCBLD2 | c.2060G>A p.G687E | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- DENND4B | c.1745G>A p.R582Q | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DMXL1 | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 32/230 reads (14%) | called by muse, mutect2, varscan2
- DOCK5 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 42/422 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- FLG | c.10393A>C p.S3465R | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.154); called by muse, mutect2
- FSTL5 | c.1304G>C p.R435T | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- KCTD3 | c.2080C>T p.Q694* | Nonsense Mutation (SNP) | VAF 30/205 reads (15%) | called by muse, mutect2, varscan2
- MSRB2 | c.192C>G p.Y64* | Nonsense Mutation (SNP) | VAF 64/214 reads (30%) | called by muse, mutect2
- MYO7A | c.2141G>A p.G714D | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2
- OR6B3 | c.275T>C p.I92T | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OTOGL | c.3081T>G p.F1027L (on ENST00000547103; = p.F1018L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/382 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDH9 | c.1450C>G p.R484G | Missense Mutation (SNP) | VAF 13/232 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2
- PGBD5 | c.392C>T p.A131V (on ENST00000525115; = p.A200V on NM_001258311.2) | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPFIBP2 | c.1766T>A p.L589* | Nonsense Mutation (SNP) | VAF 85/261 reads (33%) | called by muse, mutect2, varscan2
- PTPRC | c.3041C>G p.P1014R | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- RUSC1 | c.2541-1G>C p.X847_splice (on ENST00000368352 / NM_001105203.2; = p.X378_splice on NM_014328.4 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 49/198 reads (25%) | called by muse, mutect2
- SFRP1 | c.918C>G p.C306W | Missense Mutation (SNP) | VAF 52/368 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SIN3A | c.3383G>T p.R1128M | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SLC12A5 | c.3215_3235del p.R1072_R1078del (on ENST00000454036 / NM_001134771.2; = p.R1049_R1055del on NM_020708.5) | In Frame Del (DEL) | VAF 41/152 reads (27%) | called by mutect2, varscan2
- SLC39A12 | c.1626C>G p.I542M (on ENST00000377369 / NM_001145195.2; = p.I505M on NM_152725.3) | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.175); called by muse, mutect2
- SMYD5 | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTLC3 | c.590G>T p.S197I | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- SVOP | c.1460T>C p.V487A | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- TFDP1 | c.618G>A p.E206= | Splice Region (SNP) | VAF 40/64 reads (63%) | called by muse, mutect2, varscan2
- TRPS1 | c.3361G>C p.V1121L (on ENST00000220888 / NM_001330599.2; = p.V1134L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/415 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- UGT1A7 | c.126G>T p.Q42H | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UGT2A3 | c.1576A>G p.R526G | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- WDR17 | c.7T>C p.W3R | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); called by mutect2, varscan2
- ZNF701 | c.732A>C p.Q244H (on ENST00000301093; = p.Q178H on NM_018260.3) | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ADAMTS10 | c.2526A>C p.A842= | Silent (SNP) | VAF 10/191 reads (5%) | called by muse, mutect2
- ADGRL3 | c.4323G>T p.L1441= (on ENST00000506720 / NM_001322402.2; = p.L1330= on NM_015236.6) | Silent (SNP) | VAF 62/225 reads (28%) | catalogued as rs992202531; called by muse, mutect2, varscan2
- AHDC1 | c.1542G>A p.S514= | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as rs773786881; called by muse, mutect2, varscan2
- ARL1 | c.408C>G p.S136= | Silent (SNP) | VAF 47/291 reads (16%) | catalogued as COSV55370287; called by muse, mutect2, varscan2
- CCT5 | c.1014A>G p.G338= | Silent (SNP) | VAF 66/331 reads (20%) | called by muse, mutect2, varscan2
- CIC | c.1257C>A p.P419= | Silent (SNP) | VAF 16/103 reads (16%) | called by mutect2, varscan2
- CLDN8 | c.402C>G p.L134= | Silent (SNP) | VAF 46/252 reads (18%) | called by muse, mutect2, varscan2
- CMBL | c.27G>A p.P9= | Silent (SNP) | VAF 56/278 reads (20%) | catalogued as rs771628700, COSV56984719; called by muse, mutect2, varscan2
- DCC | c.3570C>T p.S1190= | Silent (SNP) | VAF 36/184 reads (20%) | called by muse, mutect2, varscan2
- DERL2 | c.432C>T p.F144= | Silent (SNP) | VAF 30/226 reads (13%) | catalogued as rs773347980, COSV50147780; called by muse, mutect2, varscan2
- DSEL | c.2788C>A p.R930= | Silent (SNP) | VAF 50/185 reads (27%) | catalogued as rs1434135262, COSV59494555, COSV59494633; called by mutect2, varscan2
- FAM47A | c.1212C>G p.P404= | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as COSV60499677; called by muse, mutect2, varscan2
- FAM71C | c.513C>T p.Y171= | Silent (SNP) | VAF 52/305 reads (17%) | catalogued as rs760070227; called by muse, mutect2, varscan2
- FBXO24 | c.240A>G p.R80= (on ENST00000241071 / NM_033506.3; = p.R118= on NM_012172.5) | Silent (SNP) | VAF 32/166 reads (19%) | called by muse, mutect2, varscan2
- GOLIM4 | c.1413G>A p.P471= | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as rs370924739; called by mutect2, varscan2
- GPR42 | c.1023G>A p.V341= | Silent (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- GUCA1C | c.201C>T p.N67= | Silent (SNP) | VAF 33/137 reads (24%) | catalogued as rs1439783424; called by muse, mutect2, varscan2
- MARK3 | c.885C>T p.R295= | Silent (SNP) | VAF 68/279 reads (24%) | catalogued as rs370093733; called by muse, mutect2, varscan2
- NDST2 | c.1446G>A p.R482= | Silent (SNP) | VAF 25/185 reads (14%) | called by muse, mutect2, varscan2
- NSFL1C | c.417G>A p.K139= | Silent (SNP) | VAF 21/197 reads (11%) | called by muse, mutect2, varscan2
- TRIM68 | c.1141C>A p.R381= | Silent (SNP) | VAF 31/161 reads (19%) | catalogued as COSV100331659, COSV56168250; called by muse, mutect2, varscan2
- WDFY3 | c.8280A>G p.T2760= | Silent (SNP) | VAF 35/230 reads (15%) | called by muse, mutect2, varscan2
- ATAD2B | c.*25C>G | 3'UTR (SNP) | VAF 32/249 reads (13%) | catalogued as rs372341354; called by muse, mutect2, varscan2
- C7orf57 | c.-61G>A | 5'UTR (SNP) | VAF 8/30 reads (27%) | called by mutect2, varscan2
- CALCOCO1 | c.*36_*51del | 3'UTR (DEL) | VAF 6/65 reads (9%) | called by mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- HOGA1 | c.603+25G>A | Intron (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- MIB2 | c.*35G>A | 3'UTR (SNP) | VAF 20/84 reads (24%) | catalogued as rs753568379; called by muse, mutect2, varscan2
- MIR9-1HG | n.240G>A | RNA (SNP) | VAF 20/124 reads (16%) | called by muse, mutect2, varscan2
- PRODH2 | c.738+10G>C | Intron (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2
- SMOC2 | c.-23C>T | 5'UTR (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- SPOCK2 | c.189+1182C>T | Intron (SNP) | VAF 13/217 reads (6%) | called by muse, mutect2
- SUMF2 | c.593-37C>G | Intron (SNP) | VAF 19/96 reads (20%) | called by muse, mutect2, varscan2
